Somatic mutation profile of tumor specimen MBCProject_0734_T1K_WES (aliquot MBCProject_0734_T1K_WES_1) from CMI case MBCProject_0734, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct and lobular carcinoma; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 56.1 years (20,505 days).
Specimen MBCProject_0734_T1K_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f5c321b-c925-404e-934f-de91671184c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0734_SALIVA (Saliva), aliquot MBCProject_0734_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e9b06cfe-4e23-4ef8-917b-77fab52f64f3

The open-access MAF lists 67 somatic variants for this specimen: 47 protein-altering or splice-affecting, 12 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 12, Intron 5, Nonsense Mutation 4, Frame Shift Del 4, Splice Site 2, RNA 2, Frame Shift Ins 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 90/376 reads (24%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- AGPAT1 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 41/299 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV61247913; called by muse, mutect2, varscan2
- CDC42BPG | c.4544G>A p.S1515N | Missense Mutation (SNP) | VAF 36/223 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.039); catalogued as rs1358411013; called by muse, mutect2, varscan2
- CLCN4 | c.1810C>T p.R604W | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs760806121; called by muse, mutect2, varscan2
- CNTN3 | c.661G>A p.V221M | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as rs756141728; called by muse, mutect2
- DENND2B | c.1051C>T p.P351S | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0.01); catalogued as rs1429724223; called by muse, mutect2, varscan2
- DNAH7 | c.6554G>T p.R2185L | Missense Mutation (SNP) | VAF 53/354 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56763812; called by muse, mutect2, varscan2
- FZD10 | c.571G>A p.G191S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs1421592086; called by mutect2, varscan2
- NENF | c.343-2A>G p.X115_splice | Splice Site (SNP) | VAF 18/87 reads (21%) | catalogued as rs745905009; called by muse, mutect2
- POLG | c.3211C>T p.R1071C | Missense Mutation (SNP) | VAF 82/400 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs762593265, COSV51524432; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRAMEF4 | c.748G>A p.V250I | Missense Mutation (SNP) | VAF 187/698 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs775644555, COSV52439564; called by muse, mutect2, varscan2
- PRICKLE2 | c.1781A>G p.Q594R (on ENST00000295902; = p.Q538R on NM_198859.4) | Missense Mutation (SNP) | VAF 40/192 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs760909510; called by muse, mutect2, varscan2
- PRSS53 | c.849G>C p.E283D | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV54923717; called by muse, mutect2, varscan2
- RANBP2 | c.9446A>T p.D3149V | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1558944272, COSV51698380; called by muse, mutect2, varscan2
- SELE | c.1396G>T p.E466* | Nonsense Mutation (SNP) | VAF 40/235 reads (17%) | catalogued as COSV100324796; called by muse, mutect2, varscan2
- SLC17A1 | c.1397G>A p.R466H | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.062); catalogued as rs139792251, COSV55077092; called by muse, mutect2, varscan2
- SPATA31D1 | c.3027C>A p.D1009E | Missense Mutation (SNP) | VAF 42/167 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.172); catalogued as rs1199698893; called by muse, mutect2, varscan2
- SRC | c.1259C>T p.T420M | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs142822674; called by muse, mutect2, varscan2
- TMED4 | c.251C>G p.P84R | Missense Mutation (SNP) | VAF 42/240 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV99215635; called by muse, mutect2, varscan2
- TTN | c.37975G>C p.V12659L (on ENST00000591111; = p.V5235L on NM_003319.4) | Missense Mutation (SNP) | VAF 27/172 reads (16%) | PolyPhen benign (0.011); catalogued as rs757079194, COSV100590544; called by muse, mutect2, varscan2
- AFF2 | c.3206T>A p.V1069D | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- ANK1 | c.4183G>C p.G1395R | Missense Mutation (SNP) | VAF 102/755 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANKZF1 | c.2138del p.C713Sfs*36 | Frame Shift Del (DEL) | VAF 18/118 reads (15%) | called by mutect2, pindel
- ARID1A | c.4012dup p.S1338Ffs*107 | Frame Shift Ins (INS) | VAF 30/156 reads (19%) | called by mutect2, pindel, varscan2
- CTPS1 | c.1190-1G>A p.X397_splice | Splice Site (SNP) | VAF 28/288 reads (10%) | called by muse, mutect2
- DBH | c.241C>A p.L81I | Missense Mutation (SNP) | VAF 45/348 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- DISP3 | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH6 | c.9067C>T p.Q3023* | Nonsense Mutation (SNP) | VAF 56/265 reads (21%) | called by muse, mutect2, varscan2
- EPS8L1 | c.1664del p.P555Lfs*105 (on ENST00000201647 / NM_133180.3; = p.P428Lfs*105 on NM_017729.3) | Frame Shift Del (DEL) | VAF 63/573 reads (11%) | called by mutect2, pindel, varscan2
- HNRNPUL1 | c.731C>T p.S244L | Missense Mutation (SNP) | VAF 29/261 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- INTS6L | c.2321C>T p.A774V | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KCNH7 | c.2075T>C p.I692T | Missense Mutation (SNP) | VAF 58/436 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- LRRC2 | c.581G>T p.R194I | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- PIK3R1 | c.1411_1419del p.T471_T473del (on ENST00000521381 / NM_181523.3; = p.T201_T203del on NM_181504.4) | In Frame Del (DEL) | VAF 16/94 reads (17%) | called by mutect2, pindel, varscan2
- PTPN3 | c.2075del p.N692Mfs*10 | Frame Shift Del (DEL) | VAF 20/115 reads (17%) | called by pindel, varscan2
- RECQL5 | c.2683T>A p.L895M | Missense Mutation (SNP) | VAF 124/653 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RHOBTB2 | c.31A>G p.N11D | Missense Mutation (SNP) | VAF 66/278 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RNF114 | c.92T>A p.V31E | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SELENOI | c.680T>C p.I227T | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- SFRP1 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 61/524 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SNX27 | c.612C>G p.H204Q | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, varscan2
- SYBU | c.1688A>C p.N563T (on ENST00000276646 / NM_001099754.2; = p.N562T on NM_017786.6) | Missense Mutation (SNP) | VAF 45/333 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIO | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 43/324 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- TRPM1 | c.3107A>G p.D1036G | Missense Mutation (SNP) | VAF 61/414 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- TSHR | c.1169_1176del p.C390* | Frame Shift Del (DEL) | VAF 72/452 reads (16%) | called by mutect2, pindel, varscan2
- USP12 | c.983G>A p.W328* | Nonsense Mutation (SNP) | VAF 22/270 reads (8%) | called by muse, mutect2
- ZNF536 | c.1243A>T p.M415L | Missense Mutation (SNP) | VAF 32/209 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- BEST2 | c.555C>T p.C185= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs778305142; called by muse, mutect2, varscan2
- EXOSC9 | c.339G>A p.S113= | Silent (SNP) | VAF 17/148 reads (11%) | catalogued as rs368408281; called by muse, mutect2, varscan2
- FAT3 | c.10803C>T p.H3601= | Silent (SNP) | VAF 31/253 reads (12%) | catalogued as rs571074322, COSV53164930, COSV99972442; called by muse, mutect2, varscan2
- MATR3 | c.2115T>C p.S705= | Silent (SNP) | VAF 30/191 reads (16%) | called by muse, mutect2, varscan2
- PCDHGB4 | c.669C>T p.S223= | Silent (SNP) | VAF 38/175 reads (22%) | called by muse, mutect2, varscan2
- PLXNB3 | c.2682G>A p.V894= | Silent (SNP) | VAF 19/146 reads (13%) | called by muse, mutect2, varscan2
- SASH3 | c.627T>A p.P209= | Silent (SNP) | VAF 73/418 reads (17%) | called by muse, mutect2, varscan2
- SPATA31A3 | c.2094T>A p.S698= | Silent (SNP) | VAF 54/552 reads (10%) | called by muse, mutect2, varscan2
- SPSB4 | c.135G>A p.A45= | Silent (SNP) | VAF 35/161 reads (22%) | catalogued as rs773533519; called by muse, mutect2, varscan2
- UGT2B28 | c.852T>C p.P284= | Silent (SNP) | VAF 18/109 reads (17%) | called by muse, mutect2, varscan2
- WDR72 | c.1623C>G p.L541= | Silent (SNP) | VAF 42/200 reads (21%) | catalogued as COSV100854562; called by muse, mutect2, varscan2
- ZNF98 | c.1107G>A p.K369= | Silent (SNP) | VAF 46/348 reads (13%) | called by muse, mutect2, varscan2
- ARMCX4 | c.1039-4050G>C | Intron (SNP) | VAF 22/112 reads (20%) | catalogued as rs781960872, COSV61448686; called by muse, varscan2
- BCL11B | c.*1del | 3'UTR (DEL) | VAF 38/216 reads (18%) | called by mutect2, pindel, varscan2
- COX6A1P2 | n.75G>A | RNA (SNP) | VAF 65/338 reads (19%) | catalogued as rs778583585; called by muse, mutect2, varscan2
- DLGAP4 | c.1648+15550C>T | Intron (SNP) | VAF 6/50 reads (12%) | catalogued as rs1488835131; called by muse, mutect2
- HLA-L | n.550C>T | RNA (SNP) | VAF 47/332 reads (14%) | called by muse, mutect2, varscan2
- MASP2 | c.544+87G>A | Intron (SNP) | VAF 66/319 reads (21%) | catalogued as rs565301468, COSV101280239; called by muse, mutect2, varscan2
- MDFIC | c.-107-29_-107-24del | Intron (DEL) | VAF 50/202 reads (25%) | called by mutect2, pindel
- SMARCA4 | c.3168+15G>A | Intron (SNP) | VAF 60/381 reads (16%) | called by muse, mutect2, varscan2
